Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5505, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5505-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Prostate carcinoma. PSA 4.0. Gleason grade 3+ 3= 6, right lobe. CT1C.
PROCEDURE: Radical retropubic prostatectomy.
SPECIFIC CLINICAL QUESTION: Not stated.
OUTSIDE TISSUE DIAGNOSIS: Not stated.
PRIOR MALIGNANCY: Not stated.
CHEMORADIATION: Not stated.
ORGAN TRANSPLANT: Not stated.
IMMUNOSUPPRESSION: Not stated.
OTHER DISEASES: Not stated.

**FINAL DIAGNOSIS:**

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN SIX LYMPH NODES EXAMINED (0/6).

TCGA - EJ - 5505

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN EIGHTEEN LYMPH NODES EXAMINED (0/18).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 3 = 7.
- B. TERTIARY GLEASON 5 COMPONENT IS SEEN AND ACCOUNTS FOR LESS THAN 1% OF THE TOTAL TUMOR VOLUME.
- C. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.6 CM.
- D. THE CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- E. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. NO PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS SEEN.
- J. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT2c N0 MX.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 4.0
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	75%
WEIGHT OF PROSTATE:	47.70gm
TUMOR SIZE:	Maximum dimension: 1.6 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	No
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R1
LYMPH NODES EXAMINED:	24
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 213b5a03-882d-424a-9fd5-d953146e24b6 (TCGA-EJ-5505.B8C31900-C8A8-45A7-A71A-FA356BF78511.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).